Somatic mutation profile of tumor specimen 0DP0N4 from CCDI case PBCCTG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 23.7 years (8,652 days).
Specimen 0DP0N4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 085c8ffc-c329-46d4-878f-d96feacd8df4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DP0MR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0aa12e61-e8f8-490c-a348-419ab8439dfc

The open-access MAF lists 76 somatic variants for this specimen: 34 protein-altering or splice-affecting, 7 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Intron 16, 3'UTR 10, Silent 7, 5'UTR 5, Nonsense Mutation 2, RNA 2, 5'Flank 1, Splice Site 1, Frame Shift Del 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX3X | c.1460G>A p.R487H (on ENST00000399959; = p.R488H on NM_001356.5) | Missense Mutation (SNP) | VAF 28/233 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs796052235, CM158043, COSV67864331; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DDX3X | c.1597C>T p.R533C (on ENST00000399959; = p.R534C on NM_001356.5) | Missense Mutation (SNP) | VAF 80/141 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs1555954284, COSV67863588, COSV67863748; ClinVar: likely pathogenic; called by muse, varscan2
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 26/240 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AASDH | c.1395G>T p.E465D | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV52708293; called by muse, varscan2
- BAZ1B | c.1046C>A p.S349* | Nonsense Mutation (SNP) | VAF 30/288 reads (10%) | catalogued as COSV59989381; called by muse, varscan2
- CLMN | c.545C>T p.S182L | Missense Mutation (SNP) | VAF 122/1132 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs774847195, COSV54187839; called by muse, mutect2, varscan2
- DICER1 | c.5532G>C p.K1844N | Missense Mutation (SNP) | VAF 26/300 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1360182417; called by muse, mutect2
- GNAS | c.517G>T p.D173Y | Missense Mutation (SNP) | VAF 1423/1600 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM086831; called by muse, mutect2, varscan2
- KRT12 | c.490C>T p.R164* | Nonsense Mutation (SNP) | VAF 105/261 reads (40%) | catalogued as rs762800966, COSV52429837; called by muse, mutect2, varscan2
- PXDNL | c.2336C>T p.P779L | Missense Mutation (SNP) | VAF 159/379 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs749798804; called by muse, mutect2, varscan2
- SIN3A | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 70/182 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64582462; called by muse, mutect2, varscan2
- ZNF518A | c.2785del p.T929Lfs*2 | Frame Shift Del (DEL) | VAF 30/98 reads (31%) | catalogued as rs781933025; called by mutect2, varscan2
- ZNF595 | c.943A>G p.K315E | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs879983701, COSV59551506; called by muse, mutect2
- ZNF730 | c.598T>C p.S200P | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs1458038244, COSV74168456; called by muse, varscan2
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, varscan2
- CDK19 | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 169/4728 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CHL1 | c.1623C>G p.D541E (on ENST00000397491 / NM_001253387.1; = p.D557E on NM_006614.4) | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- DHX8 | c.2344G>A p.G782S | Missense Mutation (SNP) | VAF 48/476 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- EFCAB6 | c.1923dup p.R642Tfs*4 | Frame Shift Ins (INS) | VAF 262/636 reads (41%) | called by mutect2, varscan2
- EPRS1 | c.2553T>A p.N851K | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, varscan2
- EPRS1 | c.2542G>C p.A848P | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.633); called by muse, varscan2
- GLO1 | c.467-2A>C p.X156_splice | Splice Site (SNP) | VAF 30/157 reads (19%) | called by muse, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 25/234 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, varscan2
- KBTBD8 | c.239C>T p.T80I | Missense Mutation (SNP) | VAF 80/210 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.951); called by muse, varscan2
- MUC3A | c.8152A>T p.S2718C | Missense Mutation (SNP) | VAF 96/866 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); called by muse, varscan2
- OTOL1 | c.193A>G p.M65V | Missense Mutation (SNP) | VAF 90/285 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PAXIP1 | c.2195G>C p.G732A | Missense Mutation (SNP) | VAF 36/257 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- RHOBTB1 | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 113/251 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RSF1 | c.1489A>T p.M497L | Missense Mutation (SNP) | VAF 60/174 reads (34%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEL1L2 | c.929G>T p.G310V | Missense Mutation (SNP) | VAF 36/316 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.185); called by muse, varscan2
- SIL1 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 310/831 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- TGOLN2 | c.265A>G p.K89E | Missense Mutation (SNP) | VAF 182/5126 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.037); called by muse, mutect2
- UTY | c.2804C>T p.T935I | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- ZMYND11 | c.950G>A p.R317K | Missense Mutation (SNP) | VAF 1165/1239 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RBM26 | c.2286C>T p.N762= (on ENST00000438737 / NM_001366735.2; = p.N735= on NM_022118.5) | Silent (SNP) | VAF 4/55 reads (7%) | called by mutect2, varscan2
- SEMA4C | c.1785G>T p.L595= | Silent (SNP) | VAF 144/2890 reads (5%) | called by muse, mutect2
- TMEM260 | c.1509C>A p.V503= | Silent (SNP) | VAF 8/60 reads (13%) | called by mutect2, varscan2
- ZNF30 | c.942A>G p.K314= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV57852589; called by muse, varscan2
- ZNF394 | c.1683A>G p.L561= | Silent (SNP) | VAF 58/1119 reads (5%) | catalogued as rs1463661588, COSV61793561; called by muse, mutect2
- ZNF680 | c.1542T>A p.G514= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as rs1205061578, COSV59015786; called by muse, varscan2
- ZNF695 | c.1233G>A p.E411= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as rs879097980, COSV60587163; called by muse, mutect2
- ARFGEF2 | c.3222-64A>G | Intron (SNP) | VAF 28/272 reads (10%) | called by muse, mutect2
- ATR | c.6552+10T>C | Intron (SNP) | VAF 6/42 reads (14%) | called by muse, varscan2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 28/362 reads (8%) | called by muse, mutect2
- BCKDHA | c.485-46C>T | Intron (SNP) | VAF 140/392 reads (36%) | called by muse, mutect2, varscan2
- CA9 | c.*80T>A | 3'UTR (SNP) | VAF 84/234 reads (36%) | called by muse, mutect2, varscan2
- CBX3 | c.*33T>A | 3'UTR (SNP) | VAF 21/179 reads (12%) | called by muse, varscan2
- CEP290 | c.495+46A>T | Intron (SNP) | VAF 12/96 reads (13%) | called by muse, varscan2
- COLEC11 | c.-26-728A>G | Intron (SNP) | VAF 59/1376 reads (4%) | called by muse, mutect2
- CRB1 | c.2677-473G>A | Intron (SNP) | VAF 16/78 reads (21%) | called by muse, varscan2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 18/96 reads (19%) | called by muse, varscan2
- CTSC | c.318+6725T>G | Intron (SNP) | VAF 6/35 reads (17%) | called by muse, varscan2
- DHX16 | c.*60C>G | 3'UTR (SNP) | VAF 33/199 reads (17%) | called by muse, varscan2
- DMTF1 | c.1495-59G>T | Intron (SNP) | VAF 4/44 reads (9%) | called by mutect2, varscan2
- DMXL2 | c.8272-9C>A | Intron (SNP) | VAF 20/76 reads (26%) | catalogued as rs780598054; called by muse, varscan2
- EFHD2 | c.-1C>T | 5'UTR (SNP) | VAF 790/1516 reads (52%) | called by muse, mutect2, varscan2
- EPSTI1 | chr13:42888365 C>T | 3'Flank (SNP) | VAF 120/278 reads (43%) | catalogued as rs763326690, COSV100552604, COSV58048949; called by muse, mutect2, varscan2
- GHRHR | c.*8C>T | 3'UTR (SNP) | VAF 293/746 reads (39%) | called by muse, mutect2, varscan2
- GPSM2 | c.-30T>A | 5'UTR (SNP) | VAF 20/90 reads (22%) | called by muse, varscan2
- IFFO2 | c.-44_-33del | 5'UTR (DEL) | VAF 56/194 reads (29%) | catalogued as rs1182609989; called by mutect2, varscan2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 22/274 reads (8%) | called by muse, mutect2
- LRRC49 | c.-55T>C | 5'UTR (SNP) | VAF 25/365 reads (7%) | called by muse, mutect2
- MACF1 | c.15832-10102_15832-10101insAATTTGATTCATATAACACCTCTACTTCAGGTCCTGAGGTA | Intron (INS) | VAF 3/477 reads (1%) | called by muse*, mutect2
- MIA2 | c.*60T>A | 3'UTR (SNP) | VAF 4/16 reads (25%) | called by muse, varscan2
- OR5V1 | c.*5C>G | 3'UTR (SNP) | VAF 7/46 reads (15%) | called by muse, varscan2
- PCDHGA9 | c.2424+95A>G | Intron (SNP) | VAF 22/152 reads (14%) | called by muse, mutect2
- PCDHGB5 | chr5:141398045 G>A | 5'Flank (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 15/57 reads (26%) | called by muse, varscan2
- SENP6 | c.1848+23A>G | Intron (SNP) | VAF 4/30 reads (13%) | called by muse, varscan2
- SENP6 | c.2288+11A>T | Intron (SNP) | VAF 13/98 reads (13%) | called by muse, varscan2
- SLC22A17 | n.1784G>T | RNA (SNP) | VAF 115/955 reads (12%) | catalogued as rs1042711739; called by muse, mutect2, varscan2
- SLCO1A2 | c.1272-37C>T | Intron (SNP) | VAF 6/20 reads (30%) | called by muse, varscan2
- TM4SF4 | c.*74T>A | 3'UTR (SNP) | VAF 10/70 reads (14%) | called by muse, varscan2
- TMEM178B | c.*33A>T | 3'UTR (SNP) | VAF 41/293 reads (14%) | catalogued as rs1434668436; called by muse, varscan2
- TTC8 | c.459+44T>A | Intron (SNP) | VAF 26/191 reads (14%) | called by muse, mutect2, varscan2
- WASHC4 | c.2759-26T>A | Intron (SNP) | VAF 10/60 reads (17%) | called by muse, varscan2
